Somatic mutation profile of tumor specimen TARGET-30-PATVDP-01A (aliquot TARGET-30-PATVDP-01A-01D) from TARGET case TARGET-30-PATVDP, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 7.1 years (2,596 days).
Specimen TARGET-30-PATVDP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce42e7f8-a19d-47b3-920e-dfea36666cfb.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATVDP-10A (Blood Derived Normal), aliquot TARGET-30-PATVDP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3059aabc-9e47-498d-b806-5de1dd557d97

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 1, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 28/77 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994087, CM085230, COSV66555567, COSV66558183; ClinVar: pathogenic / likely pathogenic /  risk factor; called by muse, mutect2, varscan2
- DOCK3 | c.3119C>A p.A1040E | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV56557709; called by muse, mutect2, varscan2
- LRIF1 | c.857C>A p.A286D | Missense Mutation (SNP) | VAF 93/287 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV63898721; called by muse, mutect2, varscan2
- MAPK7 | c.1526C>A p.T509K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV55192422; called by muse, mutect2, varscan2
- MXRA5 | c.5144G>T p.G1715V | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV54254567; called by muse, mutect2, varscan2
- SIGLEC1 | c.3961G>A p.A1321T | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.503); catalogued as rs147714278, COSV99163474; called by muse, mutect2, varscan2
- TET2 | c.2851G>C p.A951P | Missense Mutation (SNP) | VAF 87/225 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54413752, COSV54439499; called by muse, mutect2, varscan2
- PPM1F | c.669G>T p.L223= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs1204758468, COSV54287198; called by muse, mutect2, varscan2
- PRKDC | c.11108-12G>T | Intron (SNP) | VAF 55/156 reads (35%) | catalogued as rs1404764142, COSV58053450, COSV58068687; called by muse, mutect2, varscan2
- WRAP53 | c.-2199T>A | 5'UTR (SNP) | VAF 56/160 reads (35%) | catalogued as COSV53852732; called by muse, mutect2, varscan2
